Somatic mutation profile of cancer-model specimen HCM-BROD-0120-C15-85A (3D Organoid, passage 8; aliquot HCM-BROD-0120-C15-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0120-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2; Age at diagnosis: 46.6 years (17,010 days).
Specimen HCM-BROD-0120-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b93ac21d-bb5b-4ec3-9fbe-ab8e9f002469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0120-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0120-C15-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af4a07fa-6d60-4581-a536-8be9ed111dd8

The open-access MAF lists 144 somatic variants for this specimen: 101 protein-altering or splice-affecting, 26 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 26, Intron 10, 3'UTR 3, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 2, 5'Flank 2, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BFSP1 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746068328; called by muse, varscan2
- CBFA2T3 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs749297800, COSV51923475; called by muse, mutect2, varscan2
- CCDC122 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs759403756; called by muse, mutect2, varscan2
- CLC | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55686147; called by muse, mutect2, varscan2
- CUL7 | c.4492C>T p.L1498F | Missense Mutation (SNP) | VAF 226/781 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1294277576, COSV54818108; called by muse, mutect2, varscan2
- DAGLB | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs760935184; called by muse, mutect2, varscan2
- DDX23 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100339612, COSV57286056; called by muse, mutect2, varscan2
- DNAH3 | c.4576G>A p.A1526T | Missense Mutation (SNP) | VAF 176/274 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as rs778679316, COSV54502367; called by muse, mutect2, varscan2
- EIF4E | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs772918368, COSV99794595; called by muse, mutect2, varscan2
- ELOVL2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572165008, COSV61154928, COSV61156004; called by muse, mutect2, varscan2
- EPB41L1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 167/652 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52443391; called by muse, mutect2, varscan2
- FAM53A | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 138/388 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs748063311; called by muse, mutect2, varscan2
- FBXL7 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 100/408 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV61647313; called by muse, mutect2, varscan2
- FLG | c.6982G>C p.E2328Q | Missense Mutation (SNP) | VAF 208/857 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs762998429, COSV64250003; called by muse, mutect2, varscan2
- FOXI1 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs749136856; called by muse, mutect2, varscan2
- GLS | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 131/202 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100290696; called by muse, mutect2, varscan2
- GNPDA1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1054193183, COSV60942726; called by muse, mutect2, varscan2
- GPRC6A | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201413211, COSV59952444; called by muse, mutect2
- GRIN3B | c.2804G>A p.R935H | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1287022184; called by muse, mutect2, varscan2
- IQCE | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1401168397; called by muse, mutect2, varscan2
- IQCF1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 137/212 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1261110904; called by muse, mutect2, varscan2
- KLHL14 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 91/598 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs767060763, COSV100808696; called by muse, mutect2, varscan2
- LARP6 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 103/145 reads (71%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1368682123; called by muse, mutect2, varscan2
- LRRN3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 22/659 reads (3%) | catalogued as rs970043745, COSV57817728; called by muse, mutect2
- MAGT1 | c.265G>A p.V89I (on ENST00000618282 / NM_001367916.1; = p.V121I on NM_032121.5) | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.153); catalogued as rs782335487; called by muse, mutect2, varscan2
- MAST2 | c.3192C>A p.H1064Q | Missense Mutation (SNP) | VAF 158/200 reads (79%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs769963617; called by muse, mutect2, varscan2
- MEPCE | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 98/1304 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52769332; called by muse, mutect2
- MIA3 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201843417; called by muse, mutect2, varscan2
- MRPL13 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.185); catalogued as rs1340922650; called by muse, mutect2, varscan2
- MYCBPAP | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 162/255 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs146029360; called by muse, mutect2, varscan2
- MYT1L | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 149/545 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs774259529, COSV101221538; called by muse, mutect2, varscan2
- NUP188 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 164/220 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753037635, COSV65363346; called by muse, mutect2, varscan2
- OR4C15 | c.641T>G p.L214R (on ENST00000314644; = p.L160R on NM_001001920.2) | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV58952960; called by muse, mutect2, varscan2
- OR5D14 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs771163642, COSV59455316; called by muse, mutect2, varscan2
- PCDHGA7 | c.507T>G p.S169R | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.049); catalogued as rs780989648, COSV53992771; called by muse, mutect2
- PLIN4 | c.1937C>T p.A646V (on ENST00000301286; = p.A661V on NM_001367868.2) | Missense Mutation (SNP) | VAF 480/488 reads (98%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs762835863, COSV56690988; called by muse, mutect2, varscan2
- PZP | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746654060; called by muse, mutect2
- RARA | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54190236; called by muse, mutect2, varscan2
- RYR1 | c.3124G>A p.V1042M | Missense Mutation (SNP) | VAF 182/385 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs540088339; called by muse, mutect2, varscan2
- SETD1B | c.194del p.V65Gfs*41 | Frame Shift Del (DEL) | VAF 123/169 reads (73%) | catalogued as COSV57349674; called by mutect2, pindel, varscan2
- SLC4A8 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 159/1233 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as rs773896386, COSV60648674, COSV60656995; called by muse, mutect2, varscan2
- TENM3 | c.5830C>T p.R1944W | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs955811797; called by muse, mutect2, varscan2
- TENM3 | c.7523G>A p.R2508H | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1328986770; called by muse, mutect2, varscan2
- TNKS2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV65415016; called by muse, mutect2, varscan2
- TRIM15 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.398); catalogued as rs746569348; called by muse, mutect2, varscan2
- TRPM3 | c.2683G>A p.V895M (on ENST00000357533 / NM_001366142.2; = p.V738M on NM_020952.6) | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs749397001; called by muse, mutect2, varscan2
- UHRF1BP1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768149677; called by muse, mutect2, varscan2
- WEE2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101285270; called by muse, mutect2, varscan2
- ZNF646 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs929304428; called by muse, mutect2, varscan2
- ZSCAN5A | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs550648749, COSV54225211; called by muse, mutect2, varscan2
- AGA | c.187_189del p.M63del | In Frame Del (DEL) | VAF 219/230 reads (95%) | called by mutect2, pindel, varscan2
- AP1G2 | c.238T>G p.F80V | Missense Mutation (SNP) | VAF 175/175 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARHGAP27 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 637/638 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ASXL3 | c.4867A>G p.T1623A | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- BRINP3 | c.1752G>C p.W584C | Missense Mutation (SNP) | VAF 96/183 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CCDC166 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDK1 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHD9 | c.1868A>C p.Q623P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CHPF2 | c.1150T>G p.F384V | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- COL6A3 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- COL8A1 | c.1536_1538del p.G513del | In Frame Del (DEL) | VAF 15/78 reads (19%) | called by pindel, varscan2
- CRHBP | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXC2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- GNAL | c.261A>T p.K87N (on ENST00000269162 / NM_001142339.3; = p.K164N on NM_182978.4) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GRIK4 | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 24/517 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- GRM2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- IL1RAPL1 | c.864del p.K288Nfs*32 | Frame Shift Del (DEL) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- INO80D | c.1817A>T p.E606V | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- INPPL1 | c.3181T>C p.S1061P | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KCNA6 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF27 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LATS1 | c.1107T>G p.N369K | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.8940C>A p.D2980E | Missense Mutation (SNP) | VAF 133/550 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP4 | c.4882T>C p.C1628R | Missense Mutation (SNP) | VAF 93/728 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP6 | c.2038G>C p.V680L | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2
- MAU2 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- MDH1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- MMP17 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.326); called by muse, mutect2
- MUC5AC | c.16585+2T>G p.X5529_splice | Splice Site (SNP) | VAF 133/352 reads (38%) | called by muse, mutect2, varscan2
- MYO18A | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 21/784 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- NLRP2 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PCDHA1 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PCDHGB1 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 90/584 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- POU6F2 | c.1071C>G p.S357R | Missense Mutation (SNP) | VAF 47/468 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PRRX1 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PSMA8 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PTPRN2 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 118/257 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAG | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 142/295 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SCN2A | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 124/418 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A4 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 194/538 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- STAG1 | c.1000dup p.Y334Lfs*8 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- STARD9 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TGM4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THEGL | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 165/329 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TMEM131L | c.1595G>A p.W532* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.2903C>A p.T968K | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2
- TTN | c.2434G>T p.A812S (on ENST00000591111; = p.A766S on NM_003319.4) | Missense Mutation (SNP) | VAF 89/336 reads (26%) | PolyPhen benign (0.04); called by muse, mutect2, varscan2
- VSIG1 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XCR1 | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 57/395 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZMYND12 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ZNF121 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCC12 | c.759G>A p.A253= | Silent (SNP) | VAF 77/220 reads (35%) | catalogued as rs778359631, COSV60912543; called by muse, mutect2, varscan2
- ADHFE1 | c.957C>T p.I319= | Silent (SNP) | VAF 237/327 reads (72%) | catalogued as rs768261247; called by muse, mutect2, varscan2
- BTN3A1 | c.1356A>G p.K452= | Silent (SNP) | VAF 181/275 reads (66%) | called by muse, mutect2, varscan2
- C8orf74 | c.543C>T p.D181= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as rs542619097; called by muse, mutect2, varscan2
- DCHS1 | c.4173G>A p.A1391= | Silent (SNP) | VAF 37/269 reads (14%) | called by muse, mutect2, varscan2
- DISP2 | c.2460G>A p.R820= | Silent (SNP) | VAF 115/465 reads (25%) | called by muse, mutect2, varscan2
- DOCK2 | c.2097C>T p.Y699= | Silent (SNP) | VAF 87/320 reads (27%) | catalogued as rs1322913885; called by muse, mutect2, varscan2
- DSCAM | c.2919C>T p.N973= | Silent (SNP) | VAF 230/518 reads (44%) | catalogued as rs200413358, COSV101259586; called by muse, mutect2, varscan2
- EIF3B | c.981C>T p.V327= | Silent (SNP) | VAF 67/248 reads (27%) | called by muse, mutect2, varscan2
- GPR151 | c.399C>G p.A133= | Silent (SNP) | VAF 145/191 reads (76%) | called by muse, mutect2, varscan2
- HMCN2 | c.15075C>T p.R5025= | Silent (SNP) | VAF 147/316 reads (47%) | called by muse, mutect2, varscan2
- HSPG2 | c.11313G>A p.L3771= | Silent (SNP) | VAF 79/79 reads (100%) | called by muse, mutect2, varscan2
- IRX1 | c.1050G>A p.A350= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs1445451035; called by muse, mutect2
- KIAA0100 | c.5478C>T p.A1826= | Silent (SNP) | VAF 94/347 reads (27%) | catalogued as rs762919377; called by muse, mutect2, varscan2
- KLHL4 | c.1437T>C p.Y479= | Silent (SNP) | VAF 91/91 reads (100%) | catalogued as rs1461340187; called by muse, mutect2, varscan2
- LRRN3 | c.1533C>T p.I511= | Silent (SNP) | VAF 20/630 reads (3%) | called by muse, mutect2
- NAP1L2 | c.639A>G p.E213= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV65172720; called by muse, mutect2, varscan2
- PCDHB4 | c.525T>G p.S175= | Silent (SNP) | VAF 48/290 reads (17%) | catalogued as rs1418751080; called by muse, mutect2, varscan2
- PCDHGB4 | c.1392G>A p.P464= | Silent (SNP) | VAF 68/345 reads (20%) | catalogued as COSV54010566; called by muse, mutect2, varscan2
- RAB22A | c.528C>T p.G176= | Silent (SNP) | VAF 87/355 reads (25%) | catalogued as rs758247390, COSV54832762; called by muse, mutect2, varscan2
- SHROOM3 | c.5337C>A p.V1779= | Silent (SNP) | VAF 44/195 reads (23%) | called by muse, mutect2, varscan2
- TARBP1 | c.249C>A p.G83= | Silent (SNP) | VAF 70/105 reads (67%) | called by muse, mutect2, varscan2
- THSD4 | c.591C>A p.R197= | Silent (SNP) | VAF 319/435 reads (73%) | called by muse, mutect2, varscan2
- TTBK2 | c.615A>G p.R205= | Silent (SNP) | VAF 49/308 reads (16%) | catalogued as rs1270493035; called by muse, mutect2, varscan2
- TTC38 | c.396A>G p.E132= | Silent (SNP) | VAF 97/195 reads (50%) | called by muse, mutect2, varscan2
- ZFP28 | c.750G>A p.K250= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as COSV56735719; called by muse, mutect2, varscan2
- ALDH2 | c.*26C>T | 3'UTR (SNP) | VAF 236/237 reads (100%) | called by muse, mutect2, varscan2
- CADM1 | c.994+40C>T | Intron (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- CHL1 | c.679+922A>C | Intron (SNP) | VAF 5/65 reads (8%) | catalogued as COSV56587897, COSV56589581; called by muse, mutect2
- FRYL | c.411+54C>T | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- HERC2P3 | chr15:20457926 G>A | 5'Flank (SNP) | VAF 18/429 reads (4%) | catalogued as rs1566825989; called by muse, mutect2
- KERA | c.*39G>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- LIMCH1 | c.935+7549A>G | Intron (SNP) | VAF 28/187 reads (15%) | catalogued as rs1489871677; called by muse, mutect2
- MPDU1 | c.508-65T>C | Intron (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- NTN5 | chr19:48673185 G>A | 5'Flank (SNP) | VAF 123/252 reads (49%) | catalogued as rs764972111; called by muse, mutect2, varscan2
- PACRGL | c.-7G>A | 5'UTR (SNP) | VAF 54/241 reads (22%) | called by muse, mutect2, varscan2
- PDHX | c.965-335_965-334del | Intron (DEL) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.919-29325C>T | Intron (SNP) | VAF 39/100 reads (39%) | catalogued as rs931925370, COSV55190789; called by muse, mutect2, varscan2
- RNF170 | chr8:42850833 G>A | 3'Flank (SNP) | VAF 266/541 reads (49%) | called by muse, mutect2, varscan2
- TINAGL1 | c.*6C>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as rs372249964; called by muse, mutect2, varscan2
- VPS51 | c.359-301A>G | Intron (SNP) | VAF 32/154 reads (21%) | called by mutect2, varscan2
- WDR61 | c.12+85A>C | Intron (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- ZNF76 | c.432+228C>T | Intron (SNP) | VAF 119/431 reads (28%) | called by muse, mutect2, varscan2
